Somatic mutation profile of tumor specimen 0DPX3V from CCDI case PBCEAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (5,011 days).
Specimen 0DPX3V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d7638df-9e28-4c6b-ba25-9626a2ca36e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPX39 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ed6acc5-c12f-4c70-bdc3-499350c7e298

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1858C>T p.R620C (on ENST00000357195 / NM_001282237.2; = p.R549C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs200835381; called by muse, varscan2
- FAM83H | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs782430933; called by muse, mutect2
- CCDC51 | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2
- HERC5 | c.2566G>A p.V856I | Missense Mutation (SNP) | VAF 63/524 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- SAPCD2 | c.-8G>T | 5'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
